Somatic mutation profile of tumor specimen MP2PRT-PASZBI-TMP1-A (aliquot MP2PRT-PASZBI-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASZBI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,039 days).
Specimen MP2PRT-PASZBI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60b09a06-3737-4def-9217-e942c06f38a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASZBI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASZBI-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0850c5e4-99d5-4039-821d-cf943f8aff24

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 66/320 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DGCR2 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 76/258 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751741293; called by muse, mutect2, varscan2
- GPR83 | c.929G>T p.C310F | Missense Mutation (SNP) | VAF 79/310 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.18); catalogued as rs551668349; called by muse, mutect2, varscan2
- LRRC37B | c.2725G>A p.A909T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs775251464; called by muse, varscan2
- SLC12A1 | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs769782252, COSV66792535; called by muse, mutect2, varscan2
- STAB2 | c.3949C>T p.R1317* | Nonsense Mutation (SNP) | VAF 24/206 reads (12%) | catalogued as rs200863905; called by muse, mutect2, varscan2
- ZNF717 | c.2513G>A p.G838E | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as rs78738705, COSV68864264; called by muse, mutect2, varscan2
- MUC17 | c.7468T>C p.S2490P | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2
- RACK1 | c.290C>T p.T97I | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- CFAP61 | c.2910C>T p.N970= | Silent (SNP) | VAF 81/213 reads (38%) | catalogued as rs371975857; called by muse, mutect2, varscan2
- TECTA | c.3303C>T p.I1101= | Silent (SNP) | VAF 73/267 reads (27%) | catalogued as rs375594822; called by muse, mutect2, varscan2
- UNC79 | c.2568C>A p.I856= (on ENST00000393151 / NM_001346218.2; = p.I679= on NM_020818.5) | Silent (SNP) | VAF 22/509 reads (4%) | catalogued as rs753083118; called by muse, mutect2
